National Lung Screening Trial (NLST) participant 201686 — screening results and CT findings
Open-access record from the public subset of National Lung Screening Trial clinical data distributed by the NCI Imaging Data Commons (release v24, collection nlst). NLST enrolled current and former heavy smokers aged 55–74 in 2002–2004 and randomised them to three annual screens (T0, T1, T2) with low-dose CT or chest radiography, with follow-up through 2009. Coded values are written out from the NLST data dictionaries; day counts are days from randomisation.
https://doi.org/10.7937/TCIA.HMQ8-J677

Participant
Age at randomisation: 58 years; Gender: female; Race: White; Cigarette smoking status at randomisation: current smoker; Enrolled through an American College of Radiology Imaging Network (ACRIN) centre (from the participant ID range).

Screening results (official result of each annual screen after comparison with prior images; this participant has CT screening exam records, so these are low-dose CT screens)
- T0 (day 0): Negative screen, minor abnormalities not suspicious for lung cancer. Exam quality: diagnostic CT; technique as recorded on the form: 123 kVp, 90 mA, display field of view 28 cm, reconstruction filter GE Standard.
- T1 (day 407): Negative screen, minor abnormalities not suspicious for lung cancer. Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 80 mA, display field of view 30 cm, reconstruction filter GE Standard.
- T2 (day 810): Negative screen, minor abnormalities not suspicious for lung cancer. Isolation read, before comparison with prior images: positive (nodule(s) >= 4 mm, mass or other suspicious abnormality). Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 80 mA, display field of view 33 cm, reconstruction filter GE Standard.

Abnormalities recorded by the reading radiologist on the CT screens (15 abnormalities; numbered within each screening year; size, margins, attenuation and location were collected only for non-calcified nodules or masses of at least 4 mm; interval-change items come from the comparison read)
- T0 abnormality 1: Benign lung nodule(s) (benign calcification).
- T0 abnormality 2: Benign lung nodule(s) (benign calcification).
- T0 abnormality 3: Emphysema.
- T1 abnormality 1: Non-calcified micronodule(s) (opacity < 4 mm diameter).
- T1 abnormality 2: Emphysema.
- T1 abnormality 3: Reticular/reticulonodular opacities, honeycombing, fibrosis, scar.
- T1 abnormality 4: Chest wall abnormality (bone destruction, metastasis, etc.).
- T1 abnormality 5: Other minor abnormality noted.
- T2 abnormality 1: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the right upper lobe; longest diameter 7 mm, longest perpendicular diameter 6 mm; margins spiculated (stellate); predominant attenuation soft tissue; greatest diameter on CT slice 85; pre-existing on earlier images (earliest visible day 0); no interval growth; no suspicious change in attenuation.
- T2 abnormality 2: Benign lung nodule(s) (benign calcification).
- T2 abnormality 3: Emphysema.
- T2 abnormality 4: Reticular/reticulonodular opacities, honeycombing, fibrosis, scar.
- T2 abnormality 5: Other minor abnormality noted.
- T2 abnormality 6: Other minor abnormality noted.
- T2 abnormality 7: Other potentially significant abnormality below the diaphragm.

Follow-up
No confirmed lung cancer during the trial; Last known free of lung cancer: day 2,367.
